RC case RC-B6E9 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d2f89c39-c878-405a-97a6-f8b97e3833cf

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1948; Vital status: Dead; Days to death: 9 days; Year of death: 2021; Cause of death: Cancer Related.

Diagnoses (2)
1. Peripheral T-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9702/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 73.7 years (26,936 days); Year of diagnosis: 2021; Method of diagnosis: Bone Marrow Aspirate; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk; Sites of involvement: Lymph Node, Cervical / Lymph Node, Inguinal / Bone marrow / Liver / Peripheral blood / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 5.3 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin + Etoposide; Initial disease status: Initial Diagnosis; Days to treatment start: 9 days; Days to treatment end: 9 days; Reason treatment ended: Death; Timepoint category: First Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Myeloid leukemia, NOS: ICD-O-3 morphology code: 9860/3; Tissue or organ of origin: Blood; Classification of tumor: Prior primary; Age at diagnosis: 54.2 years (19,798 days); Year of diagnosis: 2002; Days to diagnosis: -7,138 days (-19.5 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cytarabine + Decitabine; Days to treatment start: -7,015 days (-19.2 years); Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.

Follow-up (1 entry)
- Day 9 (end of treatment course 1): Disease response: With Tumor.

Molecular and laboratory tests
- Lactate Dehydrogenase 11455 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus: Positive [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Headache.
- Timepoint category: Prior to Diagnosis; Risk factors: Myelodysplastic Syndrome.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample RC-B6E9-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B6E9-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
